CCDI case PBBYDB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/dd5d345f-25c5-4df9-978e-dbf32cb3e7e1

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.3 years (5,572 days).

Biospecimens (3 samples)
- Sample 0DKF9W: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DKRCB: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DKRD0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
